CCDI case PBCHMG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/157b6bca-6188-42aa-87e1-c7ec0fc99693

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.4 years (1,965 days).

Biospecimens (3 samples)
- Sample 0DS6KQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DS6L5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DS6LJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
